Somatic mutation profile of tumor specimen C3L-00908-03 (aliquot CPT0086360009) from CPTAC case C3L-00908, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 60.7 years (22,179 days).
Specimen C3L-00908-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b172ba9d-fac4-4a88-ac42-56de7b4d2f10.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00908-31 (Blood Derived Normal), aliquot CPT0087380001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d278be04-e60f-4019-a31d-9ed75074d32b

The open-access MAF lists 76 somatic variants for this specimen: 57 protein-altering or splice-affecting, 11 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 11, Intron 7, Nonsense Mutation 4, Frame Shift Del 3, In Frame Del 2, Splice Site 1, Splice Region 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 94/440 reads (21%) | catalogued as rs5030813, CM961428, COSV56543950, COSV56550839; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACP3 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.576); catalogued as COSV100313282; called by muse, mutect2, varscan2
- BAP1 | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 83/426 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553645794, COSV99963208; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BOC | c.1135C>T p.L379F | Missense Mutation (SNP) | VAF 18/314 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as rs1190098919; called by muse, mutect2
- CHGB | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 24/301 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.744); catalogued as rs373817587, COSV100972942; called by muse, mutect2
- CROCC | c.1994A>G p.H665R | Missense Mutation (SNP) | VAF 46/600 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.796); catalogued as rs1311137469; called by muse, mutect2
- CTNNB1 | c.1915C>T p.P639S | Missense Mutation (SNP) | VAF 117/475 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.296); catalogued as rs1304150324; called by muse, mutect2, varscan2
- DHX16 | c.2224G>A p.A742T | Missense Mutation (SNP) | VAF 42/315 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.235); catalogued as COSV53312842; called by muse, mutect2, varscan2
- EPHB2 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1459453657; called by muse, mutect2
- GOLM2 | c.311G>C p.R104T | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs763287981; called by muse, varscan2
- H3-3B | c.91C>A p.P31T | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as COSV54667031; called by muse, mutect2
- LRRC8A | c.211G>A p.G71S | Missense Mutation (SNP) | VAF 50/216 reads (23%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as rs144778925; called by muse, mutect2, varscan2
- NR1I3 | c.128T>C p.I43T | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs747349033, COSV63468902; called by muse, mutect2, varscan2
- OR2A2 | c.796C>T p.R266* | Nonsense Mutation (SNP) | VAF 63/340 reads (19%) | catalogued as rs536132673, COSV68872204; called by muse, mutect2, varscan2
- PNPLA6 | c.3359T>C p.L1120P (on ENST00000414982 / NM_001166111.2; = p.L1072P on NM_006702.5) | Missense Mutation (SNP) | VAF 119/792 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55373482; called by muse, mutect2, varscan2
- RIMS1 | c.2993G>A p.R998Q | Missense Mutation (SNP) | VAF 39/256 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.099); catalogued as rs1414432029, COSV53450436; called by muse, mutect2, varscan2
- SEC16A | c.6758G>A p.G2253D | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as rs896059806; called by muse, mutect2, varscan2
- SETBP1 | c.3669G>C p.K1223N | Missense Mutation (SNP) | VAF 100/661 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs1172547169; called by muse, mutect2, varscan2
- SF3B1 | c.2318T>G p.L773R | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59223584; called by muse, mutect2
- SLC7A1 | c.281C>T p.T94M | Missense Mutation (SNP) | VAF 65/377 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs756760070, COSV66330180; called by muse, mutect2, varscan2
- STIM1 | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 57/349 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.268); catalogued as rs1338973695, COSV56157113; called by muse, mutect2, varscan2
- ZNF404 | c.1204C>T p.Q402* | Nonsense Mutation (SNP) | VAF 6/108 reads (6%) | catalogued as rs1259147586; called by muse, mutect2
- ABAT | c.1472T>A p.I491N | Missense Mutation (SNP) | VAF 130/667 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ABCG5 | c.634A>C p.K212Q | Missense Mutation (SNP) | VAF 105/583 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- ADAMTS12 | c.634+5T>G | Splice Region (SNP) | VAF 74/349 reads (21%) | called by muse, mutect2, varscan2
- AKIRIN2 | c.226C>A p.L76I | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ATIC | c.388A>C p.T130P | Missense Mutation (SNP) | VAF 52/405 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- BCR | c.3536T>A p.F1179Y | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- BHLHE22 | c.334G>A p.G112S | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.762); called by muse, mutect2
- COPG1 | c.939+1G>C p.X313_splice | Splice Site (SNP) | VAF 28/143 reads (20%) | called by muse, mutect2, varscan2
- CROCC2 | c.3715del p.L1239Sfs*156 | Frame Shift Del (DEL) | VAF 9/77 reads (12%) | called by mutect2, pindel
- FCHSD1 | c.1268_1270del p.R423del | In Frame Del (DEL) | VAF 26/186 reads (14%) | called by pindel, varscan2
- FUT10 | c.709T>C p.Y237H | Missense Mutation (SNP) | VAF 17/266 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.058); called by muse, mutect2
- GOLIM4 | c.1664A>G p.N555S | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HDAC10 | c.173A>T p.E58V | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.772); called by muse, varscan2
- HELZ2 | c.2519G>A p.S840N (on ENST00000467148 / NM_001037335.2; = p.S271N on NM_033405.3) | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HINT3 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ITIH4 | c.1200T>A p.N400K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2
- MCTP2 | c.78G>T p.K26N | Missense Mutation (SNP) | VAF 46/214 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- MYO5A | c.755A>T p.Q252L | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- NQO1 | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 10/300 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- NUTM2G | c.518G>T p.G173V | Missense Mutation (SNP) | VAF 66/776 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.268); called by muse, mutect2
- PBRM1 | c.2039del p.L680Pfs*6 | Frame Shift Del (DEL) | VAF 14/112 reads (13%) | called by mutect2, pindel, varscan2
- PHF8 | c.2386A>G p.S796G (on ENST00000357988 / NM_001184896.1; = p.S760G on NM_015107.3) | Missense Mutation (SNP) | VAF 58/336 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.107); called by muse, varscan2
- PLCH1 | c.1043G>T p.W348L (on ENST00000340059 / NM_001130960.2; = p.W360L on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLCL2 | c.2745del p.V916Wfs*18 (on ENST00000615277 / NM_001144382.2; = p.V790Wfs*18 on NM_015184.5) | Frame Shift Del (DEL) | VAF 31/112 reads (28%) | called by mutect2, pindel, varscan2
- PRDM16 | c.3067C>A p.L1023M | Missense Mutation (SNP) | VAF 30/280 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- SLC27A4 | c.433G>A p.G145S | Missense Mutation (SNP) | VAF 39/236 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SORCS1 | c.2709_2711del p.K903del | In Frame Del (DEL) | VAF 41/171 reads (24%) | called by mutect2, pindel, varscan2
- SPATS2 | c.382G>A p.G128S | Missense Mutation (SNP) | VAF 37/260 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- SPECC1L | c.812dup p.L271Ffs*16 | Frame Shift Ins (INS) | VAF 136/775 reads (18%) | called by mutect2, pindel, varscan2
- SUN3 | c.386A>C p.Q129P | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- TCN1 | c.425C>G p.T142S | Missense Mutation (SNP) | VAF 78/488 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TIMM17B | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2
- TMEM68 | c.952G>A p.A318T (on ENST00000434581 / NM_001363177.1; = p.A251T on NM_152417.3) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UBN1 | c.3136A>G p.I1046V | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZMAT3 | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 15/368 reads (4%) | called by muse, mutect2
- CFP | c.1200C>T p.T400= | Silent (SNP) | VAF 24/573 reads (4%) | called by muse, mutect2
- COL6A6 | c.3495G>A p.K1165= | Silent (SNP) | VAF 10/208 reads (5%) | catalogued as COSV62018504, COSV62032984; called by muse, mutect2
- CREB5 | c.1482C>T p.L494= (on ENST00000357727 / NM_182898.4; = p.L487= on NM_004904.3) | Silent (SNP) | VAF 21/172 reads (12%) | called by muse, mutect2, varscan2
- DNAH5 | c.12963C>T p.D4321= | Silent (SNP) | VAF 133/739 reads (18%) | catalogued as rs768902025; called by muse, mutect2, varscan2
- KAT6A | c.5772C>T p.S1924= | Silent (SNP) | VAF 29/144 reads (20%) | catalogued as COSV55907098; called by muse, mutect2, varscan2
- KCNS1 | c.1422G>A p.V474= | Silent (SNP) | VAF 17/436 reads (4%) | called by muse, mutect2
- LPIN3 | c.1695C>T p.D565= | Silent (SNP) | VAF 44/182 reads (24%) | catalogued as rs1352186685; called by muse, mutect2, varscan2
- POM121 | c.2154C>G p.A718= (on ENST00000434423; = p.A453= on NM_172020.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 60/1244 reads (5%) | catalogued as rs1554501250; called by muse, mutect2
- PTPRC | c.36T>C p.F12= | Silent (SNP) | VAF 77/456 reads (17%) | called by muse, mutect2, varscan2
- SMPDL3A | c.789C>T p.N263= | Silent (SNP) | VAF 5/73 reads (7%) | called by muse, mutect2
- SQSTM1 | c.729T>C p.S243= | Silent (SNP) | VAF 124/794 reads (16%) | called by muse, mutect2, varscan2
- AC092329.3 | c.-211-589G>C | Intron (SNP) | VAF 46/304 reads (15%) | called by muse, mutect2, varscan2
- NPIPP1 | n.845A>T | RNA (SNP) | VAF 136/870 reads (16%) | called by muse, varscan2
- OR9Q1 | c.-15+53346A>T | Intron (SNP) | VAF 53/355 reads (15%) | called by muse, mutect2, varscan2
- PLEKHS1 | c.929+30C>A | Intron (SNP) | VAF 57/280 reads (20%) | called by muse, mutect2, varscan2
- PSMA4 | c.-23-25dup | Intron (INS) | VAF 4/32 reads (13%) | called by mutect2, varscan2
- RBM22 | c.55-71C>A | Intron (SNP) | VAF 14/139 reads (10%) | called by muse, mutect2, varscan2
- SLC2A11 | c.21+33C>G | Intron (SNP) | VAF 23/160 reads (14%) | called by muse, mutect2, varscan2
- WDR49 | c.-66+19734G>C | Intron (SNP) | VAF 18/164 reads (11%) | called by muse, mutect2
